CCDI case PBCLXD — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Connective, subcutaneous and other soft tissues.
https://portal.gdc.cancer.gov/cases/6b1dd176-7fde-4f07-9d33-8233d3d8eba3

Demographics
Sex at birth: male; Race: black or african american.

Diagnoses (1)
1. Rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8900/3; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of pelvis; Age at diagnosis: 14.6 years (5,348 days).

Biospecimens (3 samples)
- Sample 0DUVT7: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Samples 0DUVTG, 0DUVUY (2 with the same recorded description): Tissue type: Tumor; Specimen type: Solid Tissue.
